FM case AD17186 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Other and ill-defined sites.
https://portal.gdc.cancer.gov/cases/c1a61a3b-419e-477f-9588-b21c49023eeb

Female, 52.3 years: Squamous cell carcinoma, NOS (ICD-O-3 8070/3) of the head, face or neck; specimen biopsied or resected from the tongue. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Tumor.
